Somatic mutation profile of tumor specimen TCGA-B2-3923-01A (aliquot TCGA-B2-3923-01A-01D-1458-08) from TCGA case TCGA-B2-3923, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 59.7 years (21,793 days).
Specimen TCGA-B2-3923-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7d5d5ea-9e62-450f-9ddd-5e59bb4d5a1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B2-3923-10A (Blood Derived Normal), aliquot TCGA-B2-3923-10A-01D-1458-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8d86082-df49-4938-b0af-b087371c9008

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, In Frame Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM30 | c.97C>T p.H33Y | Missense Mutation (SNP) | VAF 45/64 reads (70%) | SIFT tolerated (0.41); PolyPhen benign (0.356); catalogued as COSV65560659; called by muse, mutect2, varscan2
- AHSA1 | c.941G>T p.R314L | Missense Mutation (SNP) | VAF 69/333 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.827); catalogued as COSV53631343, COSV53632886; called by muse, mutect2
- DCAF12L2 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs1338664181, COSV63580237, COSV63583223; called by muse, mutect2, varscan2
- DOP1B | c.6083T>C p.M2028T | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs996130220, COSV67692664; called by muse, mutect2, varscan2
- FERMT1 | c.1757C>T p.S586L | Missense Mutation (SNP) | VAF 8/183 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV54091896; called by muse, mutect2
- GAN | c.968C>A p.S323* | Nonsense Mutation (SNP) | VAF 46/125 reads (37%) | catalogued as COSV73720808; called by muse, mutect2, varscan2
- NGLY1 | c.1672G>T p.G558W | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV54985128; called by muse, mutect2, varscan2
- NUP62CL | c.336T>G p.N112K | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV65235559; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1337T>C p.V446A (on ENST00000259318 / NM_001136562.3; = p.V677A on NM_007203.5) | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as COSV52174675; called by muse, mutect2
- PJA2 | c.1539T>G p.S513R | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63272221; called by muse, mutect2, varscan2
- SCUBE2 | c.1117A>T p.T373S | Missense Mutation (SNP) | VAF 19/276 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV58541557; called by muse, mutect2
- TRPM4 | c.215C>A p.T72N | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs759027293, COSV53261327, COSV53264648; called by muse, mutect2, varscan2
- USP15 | c.441_443del p.V148del | In Frame Del (DEL) | VAF 110/354 reads (31%) | catalogued as rs1397041029; called by pindel, varscan2
- SLC24A2 | c.1668_1670del p.R557del | In Frame Del (DEL) | VAF 10/106 reads (9%) | called by mutect2, pindel
- C3orf20 | c.681C>T p.Y227= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV53783635; called by muse, mutect2, varscan2
- HYAL4 | c.1185C>T p.P395= | Silent (SNP) | VAF 62/151 reads (41%) | catalogued as COSV56137995; called by muse, varscan2
- SMARCA5 | c.1365A>G p.K455= | Silent (SNP) | VAF 9/124 reads (7%) | catalogued as COSV51643094; called by muse, mutect2
